Somatic mutation profile of tumor specimen MP2PRT-PASRBU-TMP1-A (aliquot MP2PRT-PASRBU-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASRBU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,988 days).
Specimen MP2PRT-PASRBU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1505a0c0-54dd-4a79-9d97-80743fc3caca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRBU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRBU-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f12995dd-4933-408b-a05e-a2c4f70cb803

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ARSI | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 113/579 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs140478189; called by muse, mutect2, varscan2
- CDKL1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs777979509; called by muse, mutect2, varscan2
- HCN1 | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 265/555 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs147007826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPH | c.1720G>C p.V574L (on ENST00000343002; = p.V307L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs756487056; called by muse, mutect2, varscan2
- PKN3 | c.2407G>A p.G803R | Missense Mutation (SNP) | VAF 221/523 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747755433, COSV99403494; called by muse, mutect2, varscan2
- RGS12 | c.4339G>A p.V1447I (on ENST00000336727; = p.V799I on NM_198227.2) | Missense Mutation (SNP) | VAF 75/419 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs950260405; called by muse, mutect2, varscan2
- KCNQ3 | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 153/328 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKRN1 | c.64A>C p.T22P | Missense Mutation (SNP) | VAF 158/724 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCERG1L | c.1606A>G p.T536A | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PRPF38A | c.652C>A p.R218= | Silent (SNP) | VAF 80/400 reads (20%) | called by muse, mutect2, varscan2
